Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7J1, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7J1-01A (Primary Tumor).

ICD-O.3
Oligodendroglioma, grade II
9450/3
Site Brain, supratentorial NC
C71.0
JW 9/30/13

oligodendroglial Tumor with IDH R132H mutation
and 1p/19q loss

Diagnosis: oligodendroglioma WHO grade II

untranslated original report
is housed at the BCR.

Criteria:	JW 8/30/13	Yes	No

Source: NCI Genomic Data Commons file ca33ca89-054d-4146-9f82-3a7c555ca9f9 (TCGA-S9-A7J1.60CE3E08-7253-47C7-B7FF-567CF0974988.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).